Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A3PR, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A3PR-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: THYROID, TOTAL THYROIDECTOMY -

- A. PAPILLARY THYROID CARCINOMA, OF RIGHT LOBE, 2.5 CM.
- B. CARCINOMA INVADES THE PERI-THYROIDAL SOFT TISSUE.
- C. CARCINOMA DOES NOT INVADE THE SKELETAL MUSCLE.
- D. NO DEFINITE LYMPHOVASCULAR INVASION IDENTIFIED.
- E. CARCINOMA FOCALLY PRESENT AT THE PERIPHERAL SURGICAL MARGIN.
- F. REMAINING THYROID PARENCHYMA WITH HASHIMOTO THYROIDITIS AND HÜRTLE CELL NODULES.
- G. ONE CENTRAL LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)
- H. TNM STAGE (AJCC, 7th Edition): p T1 N0.

PART 2: CONTENTS, CENTRAL COMPARTMENT, EXCISION - FIVE BENIGN REACTIVE LYMPH NODES (0/5).

COMMENT:

Selected slides of part 1 of this case were reviewed by [REDACTED] who agree with the diagnosis.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE:	Total Thyroidectomy
TUMOR SITE:	Right Lobe
TUMOR FOCALITY:	Unifocal
TUMOR SIZE (largest nodule):	Greatest Dimension: 2.5 cm Additional Dimensions: 2 cm
HISTOLOGIC TYPE**:	Papillary carcinoma
PRIMARY TUMOR (pT):	pT2
REGIONAL LYMPH NODES (pN):	pN0
	Number of regional lymph nodes examined: 6 Number of regional lymph nodes involved: 0
EXTRANODAL EXTENSION:	Present
DISTANT METASTASIS (pM):	Not applicable
EXTRATHYROIDAL EXTENSION:	Present
MARGINS:	Margin(s) involved by carcinoma
LYMPH-VASCULAR INVASION:	Not identified
ADDITIONAL PATHOLOGIC FINDINGS:	Thyroiditis

ADDENDA:

Addendum

This addendum is to clarify the pathologic tumor stage. This does not change the prior diagnosis.
The pathologic tumor stage is 'pT2 N0'.

ICA-0-3

Carcinoma, papillary, thyroid, 8260/3

Site: thyroid, NOS 873.9

hw
2/15/12

Source: NCI Genomic Data Commons file 241e98e4-0f49-4c3e-82b6-e3a24632002d (TCGA-BJ-A3PR.9C4A4B7A-9341-404C-9804-6B91FDFC3F2C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).